Somatic mutation profile of tumor specimen HCM-CSHL-0060-C18-01B (aliquot HCM-CSHL-0060-C18-01B-01D-A77E-36) from HCMI case HCM-CSHL-0060-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 50.8 years (18,571 days).
Specimen HCM-CSHL-0060-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e09fd65e-288d-4cda-9f54-edc30defc802.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0060-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0060-C18-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6a1f05b-9eb4-4d17-96aa-b926239a09a8

The open-access MAF lists 77 somatic variants for this specimen: 61 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 8, Nonsense Mutation 4, Intron 3, 5'Flank 2, In Frame Del 2, Frame Shift Del 2, RNA 2, Splice Region 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 117/263 reads (44%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AL445989.1 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 211/790 reads (27%) | SIFT tolerated, low confidence (0.05); catalogued as rs898868096; called by mutect2, varscan2
- AMER1 | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV57666208; called by muse, mutect2, varscan2
- APC | c.4508del p.S1503Yfs*4 | Frame Shift Del (DEL) | VAF 78/258 reads (30%) | catalogued as CM000126, COSV57332733, COSV57338787; called by mutect2, pindel, varscan2
- CHID1 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs139154177; called by muse, mutect2, varscan2
- CNTNAP4 | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 58/524 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1371162409, COSV56706368; called by muse, varscan2
- DST | c.15941C>T p.T5314M (on ENST00000361203 / NM_001374722.1; = p.T2902M on NM_015548.5) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as rs756527130, COSV55014242, COSV55029896; called by muse, mutect2, varscan2
- FGF2 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 101/310 reads (33%) | catalogued as COSV52648737; called by muse, mutect2, varscan2
- GRID1 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs148165863; called by muse, mutect2, varscan2
- GRIK3 | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs746478247, COSV66135600, COSV66143041; called by muse, mutect2, varscan2
- HECTD4 | c.12745C>T p.R4249W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1415169230; called by muse, mutect2, varscan2
- JPH2 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1297647598, COSV65902416; called by mutect2, varscan2
- KY | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs760547713; called by muse, mutect2, varscan2
- LONRF2 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as rs772166966, COSV66539320; called by muse, mutect2, varscan2
- MED12 | c.4070G>A p.R1357H | Missense Mutation (SNP) | VAF 152/264 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61332408, COSV61353101; called by muse, mutect2, varscan2
- MED7 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.166); catalogued as COSV53850498; called by muse, mutect2, varscan2
- OLFML2B | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as rs750492409, COSV54198425; called by muse, mutect2, varscan2
- OR2L2 | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs373354734, COSV63547472; called by muse, mutect2, varscan2
- OR2T2 | c.839C>A p.T280N | Missense Mutation (SNP) | VAF 26/526 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369134573; called by muse, mutect2
- PCDHB8 | c.1082C>A p.A361E | Missense Mutation (SNP) | VAF 109/1023 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.279); catalogued as COSV50754565; called by muse, mutect2, varscan2
- POPDC3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 72/265 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as rs111547826, COSV54643244; called by muse, mutect2, varscan2
- RAD9A | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as rs569583450, COSV57236269; called by muse, mutect2, varscan2
- RGPD4 | c.3344C>T p.T1115M | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758889509; called by muse, mutect2, varscan2
- SAGE1 | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 87/197 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.41); catalogued as rs781798413, COSV61012362; called by muse, mutect2, varscan2
- SERPINA3 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs377262300, COSV67586294; called by muse, mutect2
- SLC26A3 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 56/476 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs765288477, COSV60641616; called by muse, mutect2, varscan2
- SYNE1 | c.3584C>A p.S1195Y (on ENST00000367255 / NM_182961.4; = p.S1202Y on NM_033071.3) | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54928469; called by muse, mutect2, varscan2
- SYTL1 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs537376314; called by muse, mutect2, varscan2
- TMPRSS15 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 44/568 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs771914509; called by muse, mutect2
- TNKS1BP1 | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as rs556509857, COSV64100553; called by muse, mutect2
- TRAPPC11 | c.1279_1281del p.V427del | In Frame Del (DEL) | VAF 106/396 reads (27%) | catalogued as rs779028056; called by pindel, varscan2
- TRPV6 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs775632242, COSV63890810; called by muse, mutect2, varscan2
- TTC28 | c.4351G>A p.G1451S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs767044155; called by muse, mutect2, varscan2
- VWA5B1 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs761851357, COSV57060835; called by mutect2, varscan2
- WBP2 | c.657C>T p.A219= | Splice Region (SNP) | VAF 60/149 reads (40%) | catalogued as rs370952739; called by muse, mutect2, varscan2
- ZFHX4 | c.2617C>T p.R873W | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756774471, COSV51497737; called by muse, mutect2, varscan2
- AADAT | c.853_870del p.I285_V290del | In Frame Del (DEL) | VAF 63/336 reads (19%) | called by mutect2, pindel, varscan2
- ADAM12 | c.2670-1G>A p.X890_splice | Splice Site (SNP) | VAF 46/272 reads (17%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.2530T>G p.F844V | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.138); called by muse, mutect2
- AMER2 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- CCDC102B | c.1190A>G p.K397R | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CCNA1 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- CEP170B | c.2018A>T p.Y673F (on ENST00000453495; = p.Y602F on NM_015005.3) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- DOCK10 | c.5000C>T p.A1667V | Missense Mutation (SNP) | VAF 15/409 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- DYNC2H1 | c.6944C>A p.T2315K | Missense Mutation (SNP) | VAF 63/488 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- EPHB6 | c.2152C>G p.L718V | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GUCY2F | c.2399C>A p.P800Q | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAKMIP3 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- LMAN2L | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LPCAT2 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); called by muse, mutect2
- MYH2 | c.4372A>T p.I1458F | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); called by muse, mutect2
- NDNF | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 16/243 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- PCLO | c.4874G>T p.R1625I | Missense Mutation (SNP) | VAF 36/441 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2
- PHF24 | c.706del p.R236Vfs*5 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- PI4KA | c.3246A>G p.E1082= | Splice Region (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2, varscan2
- POU5F2 | c.608A>G p.E203G | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2
- RELN | c.6548T>C p.L2183S | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- SPATA31A1 | c.3078A>C p.Q1026H | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- SYCP2L | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- TCF3 | c.402C>A p.S134R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- TEX14 | c.1276G>T p.E426* (on ENST00000240361 / NM_001201457.2; = p.E420* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 30/394 reads (8%) | called by muse, mutect2
- ATXN2L | c.1401C>T p.I467= | Silent (SNP) | VAF 44/418 reads (11%) | catalogued as rs376413216; called by muse, mutect2
- COX5B | c.240C>T p.V80= | Silent (SNP) | VAF 25/503 reads (5%) | catalogued as rs1012294517; called by muse, mutect2
- CTNNA2 | c.2247C>T p.A749= | Silent (SNP) | VAF 64/370 reads (17%) | catalogued as rs745517637, COSV100562552; called by muse, mutect2, varscan2
- GRM2 | c.2325A>G p.A775= | Silent (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2
- NLRP5 | c.3208C>T p.L1070= | Silent (SNP) | VAF 12/203 reads (6%) | called by muse, mutect2
- PCDHA12 | c.84C>T p.S28= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs781896642; called by muse, mutect2, varscan2
- RYR2 | c.4863T>C p.C1621= | Silent (SNP) | VAF 46/219 reads (21%) | called by muse, mutect2, varscan2
- TNRC18 | c.2331C>T p.L777= | Silent (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- AC005008.1 | chr7:81189966 T>C | 5'Flank (SNP) | VAF 26/160 reads (16%) | called by muse, mutect2, varscan2
- DAGLB | c.1141-12C>T | Intron (SNP) | VAF 57/203 reads (28%) | called by muse, mutect2, varscan2
- FAM183BP | n.918C>T | RNA (SNP) | VAF 12/112 reads (11%) | catalogued as rs758258582; called by muse, mutect2, varscan2
- LINC01553 | n.1191dup | RNA (INS) | VAF 75/277 reads (27%) | called by mutect2, varscan2
- LMBR1L | c.72+706C>T | Intron (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2
- SHCBP1L | chr1:182953182 C>T | 5'Flank (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- SLC14A1 | c.-22+2286G>A | Intron (SNP) | VAF 70/180 reads (39%) | called by muse, mutect2, varscan2
- WDFY4 | c.*46G>A | 3'UTR (SNP) | VAF 10/178 reads (6%) | catalogued as COSV99629533; called by muse, mutect2
